Somatic mutation profile of tumor specimen TCGA-HC-7752-01A (aliquot TCGA-HC-7752-01A-11D-2114-08) from TCGA case TCGA-HC-7752, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.2 years (22,366 days).
Specimen TCGA-HC-7752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cac0f74-eaeb-4d5d-8824-6d4f01689610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7752-10A (Blood Derived Normal), aliquot TCGA-HC-7752-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d216fef4-38af-426d-b451-a7b071d3e55f

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3656G>T p.G1219V | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV61265886; called by muse, mutect2, varscan2
- AFAP1 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as COSV61796326; called by muse, mutect2, varscan2
- ARHGAP22 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752411389, COSV50949153, COSV99986000; called by muse, mutect2, varscan2
- CNTNAP4 | c.2258T>C p.L753P | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56685862; called by muse, mutect2, varscan2
- COL18A1 | c.2780G>A p.S927N (on ENST00000359759 / NM_130444.3; = p.S692N on NM_030582.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs367836626; called by muse, mutect2, varscan2
- DLK2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV55089325; called by muse, mutect2, varscan2
- ERICH3 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.286); catalogued as rs748670801, COSV100445650, COSV58605635; called by muse, mutect2, varscan2
- FCGBP | c.5657G>A p.G1886E | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs1275280591; called by muse, mutect2, varscan2
- FGFR2 | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60650187; called by muse, mutect2
- GAD2 | c.1275C>G p.Y425* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as COSV52160468; called by muse, mutect2, varscan2
- GRIA1 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs759869812, COSV53590645; called by muse, mutect2, varscan2
- ILKAP | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV54518576; called by muse, mutect2, varscan2
- LAMB1 | c.4835C>T p.A1612V | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55966283; called by muse, mutect2
- MRPL47 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as COSV52019518; called by muse, mutect2, varscan2
- MTA2 | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53470481, COSV53470970; called by muse, mutect2, varscan2
- PNPLA6 | c.3693C>G p.F1231L (on ENST00000414982 / NM_001166111.2; = p.F1183L on NM_006702.5) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55379793; called by muse, mutect2, varscan2
- SALL1 | c.3365T>C p.L1122P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769399017, COSV51759322; called by muse, mutect2, varscan2
- SRGAP1 | c.1803T>G p.I601M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.189); catalogued as COSV61899337; called by muse, mutect2, varscan2
- TENT4A | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV50096362; called by muse, mutect2, varscan2
- TRAM1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV51596567; called by muse, mutect2, varscan2
- WFDC6 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs1404997778, COSV60548918; called by muse, mutect2, varscan2
- UGT2B10 | c.588_589insC p.M197Hfs*6 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- USP15 | c.2278dup p.R760Kfs*4 (on ENST00000280377 / NM_001351159.2; = p.R731Kfs*4 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | called by mutect2, varscan2
- MCF2 | c.2103C>T p.S701= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs770148497, COSV58487183; called by muse, mutect2
- S100A3 | c.60A>C p.A20= | Silent (SNP) | VAF 18/263 reads (7%) | catalogued as COSV62876810; called by muse, mutect2
- TPTE2 | c.42C>T p.T14= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs144275026; called by muse, mutect2, varscan2
- WASHC2C | c.1056G>A p.S352= | Silent (SNP) | VAF 102/322 reads (32%) | catalogued as rs1554875307, COSV60491786, COSV60491992; called by muse, mutect2, varscan2
